Surgical pathology report (de-identified scan), TCGA case TCGA-86-6851, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-6851-01A (Primary Tumor).

[page 1 of 2]
	86-6851		A. Labeled left upper lobe lesion. Received fresh for intraoperative consultation is a previously incised and diffusely ragged wedge of lung measuring 7 x 3 x 2.2 cm. There are 2 firm gray and brown lesion measuring 1.0 and 1.4 cm in greatest dimension. B. Labeled left upper lobe bronchial margin. Received fresh for intraoperative consultation is a 150 g lobe of lung measuring approximately 15 x 10 x 4 cm. the pleural surface is tan to red and smooth to slightly wrinkled with two staple lines adjacent to the hilum measuring 3.8 and 13 cm in length. The larger passes through a 2.5 x 2.2 cm firm white-tan to red mass that comes to within 2.0 cm of the bronchial margin. Immediately adjacent to the bronchial margin is a 1.5 cm gray-white lymph node grossly positive for metastatic tumor. The bronchial margin and adjacent lymph node are sampled for frozen section. The background lung is tan to red and spongy with no other nodules or masses lesions. Another hilar lymph node is not identified.	Sections show a poorly differentiated invasive adenocarcinoma with both acinar and solid growth patterns. The tumor extends to the subpleura. Immunohistochemical stains are performed with appropriate control reactions to confirm this histologic impression. The malignant cells are positive for cytokeratin 7, TTF-1, Napsin-A while negative for cytokeratin 5/6. The malignant cells show rare focal positivity for p63. An elastin stain shows no convincing penetration of the visceral pleural elastic layer by the tumor.
--	---------	--	--	--

[page 2 of 2]
LUNG CARCINOMA CHECKLIST

1. Tumor type: Adenocarcinoma
2. Histologic grade: Poorly differentiated.
3. Tumor location: Left upper lobe.
4. Tumor size: 2.5 x 2.2 cm.
5. Angiolymphatic invasion: Yes.
6. Bronchial margin: The bronchus is free of tumor. However, a peribronchial lymph node at the resection margin contained metastatic tumor with extranodal extension into peribronchial soft tissues.
7. Parenchymal margin: Involved by carcinoma.
8. Vascular margins: Free of tumor.
9. Pleural involvement: Subpleural.
10. Lymph nodes: One of two peribronchial lymph nodes positive for metastatic tumor (1/2). One benign para-aortic lymph node (0/1). Four benign hilar lymph nodes (0/4).
11. Size of largest metastatic deposit: 1.3 cm.
12. TNM: pT1b, pN1, pMX.

LUNG TISSUE CHECKLIST

Specimen type:
Lobectomy
Tumor site: Lung
Tumor size: 2.5 x 2.2 cm
Histologic type:
Adenocarcinoma
Histologic grade:
Poorly differentiated
Tumor extent: Not specified
Other tumor nodules:
Not specified
Lymph nodes: 1/7 positive for metastasis (Regional 1/7)
Lymphatic invasion:
Present
Venous invasion:
Present
Margins: Involved
Evidence of neo-adjuvant treatment:
Not specified
Additional pathologic findings: Not specified
Comments: None

--

Source: NCI Genomic Data Commons file bb8e1345-b939-4c9d-b676-306fc5730545 (TCGA-86-6851.519253C3-7E47-4C66-9149-65E622F1BA29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).